Gene-level copy-number profile of tumor specimen ALCH-B43S-TTP1-A from ALCHEMIST case ALCH-B43S, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 78.8 years (28,772 days).
Specimen ALCH-B43S-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a57c9430-8937-41e1-bf70-b4ddba932b70.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B43S-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,715 have no estimate.
https://portal.gdc.cancer.gov/files/657a34c9-0597-4f17-bbdc-30ce0e6629d3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 585; copy number 1: 9,686; copy number 2: 47,901; copy number 3: 680; copy number 4: 23; copy number 5: 11; copy number 6: 13; copy number 8: 3; copy number 9: 4; copy number 10: 2.

Homozygous deletions (total copy number 0; autosomes only): 68 genes in 35 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,541,673–1,577,075, 2 genes: SSU72, AL645728.1.
- chr1:24,968,423–24,970,865, 1 gene: AL445471.1.
- chr2:27,070,472–27,071,654, 1 gene (within-gene range 0–2): OST4.
- chr2:119,679,167–119,700,151, 2 genes: TMEM177, RPL17P15.
- chr3:49,674,014–49,721,529, 4 genes (within-gene range 0–1): APEH, MST1, AC099668.1, RNF123.
- chr4:3,244,369–3,271,738, 1 gene: MSANTD1.
- chr4:49,579,833–49,589,529, 2 genes: AC119751.4, SNX18P25.
- chr5:443,175–473,098, 2 genes: EXOC3, PP7080.
- chr6:89,177,504–89,231,278, 1 gene: GABRR1.
- chr7:97,963,658–97,972,254, 5 genes: MIR5692A1, MIR5692C2, OR7E38P, AC004967.2, AC004967.1.
- chr8:9,899,871–9,906,678, 2 genes: MIR124-1HG, MIR124-1.
- chr8:33,523,154–33,600,023, 6 genes: AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P, DUSP26.
- chr8:38,421,889–38,426,096, 1 gene (within-gene range 0–1): AC087623.1.
- chr8:101,686,547–101,689,093, 1 gene (within-gene range 0–2): AP000426.1.
- chr9:37,422,666–37,436,990, 2 genes: GRHPR, CHCHD4P3.
- chr9:124,257,606–124,353,307, 3 genes (within-gene range 0–2): NEK6, AL162724.2, AL162724.1.
- chr9:124,853,417–124,857,890, 1 gene (within-gene range 0–2): WDR38.
- chr9:125,417,305–125,417,586, 1 gene: Metazoa_SRP.
- chr9:130,444,961–130,501,274, 1 gene: ASS1.
- chr10:47,995,322–48,031,640, 2 genes: FAM25C, AGAP12P.
- chr10:118,643,760–118,644,198, 1 gene: TOMM22P5.
- chr11:440,399–440,693, 1 gene (within-gene range 0–2): RN7SL838P.
- chr11:134,032,216–134,067,936, 2 genes: LINC02731, AP000911.1.
- chr15:41,848,146–41,894,053, 3 genes (within-gene range 0–2): SPTBN5, RNA5SP393, MIR4310.
- chr15:93,035,273–93,089,204, 2 genes: RGMA, YBX2P2.
- chr16:46,469,341–46,569,097, 2 genes (within-gene range 0–2): ANKRD26P1, RNU6-845P.
- chr16:68,367,325–68,370,262, 1 gene (within-gene range 0–2): AC099521.2.
- chr16:85,098,358–85,112,472, 1 gene: CIBAR2.
- chr17:30,702,504–30,702,775, 1 gene: RN7SL316P.
- chr17:30,724,982–30,731,202, 3 genes (within-gene range 0–2): AC127024.7, AC127024.3, AC127024.2.
- chr17:49,966,075–49,966,176, 1 gene: RNU6-1313P.
- chr17:50,503,412–50,531,501, 2 genes: AC021491.1, MYCBPAP.
- chr17:82,418,318–82,442,645, 2 genes (within-gene range 0–2): HEXD, HEXD-IT1.
- chr19:19,264,364–19,320,509, 2 genes (within-gene range 0–1): TM6SF2, SUGP1.
- chr21:43,865,223–43,987,592, 3 genes: AGPAT3, RNU6-859P, AP001054.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 33 genes in 13 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,598,012–1,600,135, 1 gene, copy number 9: FNDC10.
- chr6:30,489,509–30,519,217, 2 genes, copy number 5: HLA-E, LINC02569.
- chr8:144,012,280–144,047,114, 1 gene, copy number 6 (within-gene range 3–6): SPATC1.
- chr10:114,043,866–114,046,904, 1 gene, copy number 8: ADRB1.
- chr11:818,914–842,529, 5 genes, copy number 5–8: PNPLA2, AP006621.1, CRACR2B, CD151, POLR2L.
- chr11:67,414,968–67,435,401, 3 genes, copy number 6 (within-gene range 2–6): CARNS1, RPS6KB2, RPS6KB2-AS1.
- chr17:7,921,859–7,949,920, 4 genes, copy number 6: KCNAB3, AC104581.2, TRAPPC1, CNTROB.
- chr17:82,228,397–82,273,731, 5 genes, copy number 5: SLC16A3, MIR6787, CSNK1D, AC132872.3, AC132872.4.
- chr19:18,279,694–18,285,495, 3 genes, copy number 6: JUND, MIR3188, RPL39P38.
- chr21:43,446,601–43,479,534, 3 genes, copy number 6–10: LINC00319, LINC00313, AP001048.1.
- chr22:18,733,914–18,757,906, 1 gene, copy number 10: FAM230E.
- chr22:18,873,543–18,894,407, 1 gene, copy number 8 (within-gene range 2–8): FAM230F.
- chr22:18,906,028–18,947,732, 3 genes, copy number 9 (within-gene range 3–9): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 7,350. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
